Gene-level copy-number profile of tumor specimen TCGA-55-7576-01A from TCGA case TCGA-55-7576, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.5 years (19,917 days).
Specimen TCGA-55-7576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.73d9c63c-d9e5-4ff2-a4c1-2ab0b350cbc5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7576-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12c880bc-a97b-4eb6-bb88-7ef44cad6e01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 12,595; copy number 2: 23,323; copy number 3: 19,035; copy number 4: 3,132; copy number 5: 1,689.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7576-01A-11D-2062-01): tumor purity 0.47, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,264,435–151,015,727, 5 genes (within-gene range 0–2): LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1.
- chr9:21,802,636–25,089,151, 35 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,689 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,527,831–166,975,540, 626 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:168,055,901–174,995,308, 146 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:175,877,343–179,691,272, 65 genes, copy number 5 (broad region; genes not listed).
- chr5:17,511,833–30,693,984, 140 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:63,301,523–63,571,617, 2 genes, copy number 5: AC025445.1, AC008558.1.
- chr8:105,546,089–106,272,902, 9 genes, copy number 5: ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr8:112,148,742–112,148,825, 1 gene, copy number 5: RNU4-37P.
- chr12:16,989,126–31,369,301, 232 genes, copy number 5 (broad region; genes not listed).
- chr12:31,396,390–31,396,501, 1 gene, copy number 5: RNU6-618P.
- chr17:68,867,289–70,368,916, 27 genes, copy number 5: ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr17:73,067,870–83,095,122, 440 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
